Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7411, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7411-01A (Primary Tumor).

DIAGNOSIS

(A) BILATERAL SUPRAOMOHYOID NECK DISSECTION (20 LYMPH NODES, LEFT AND 9 LYMPH NODES, RIGHT):

Left parotid compartment:

Benign salivary gland and one lymph node, no tumor present.

Left neck dissection:

Nineteen lymph nodes, no squamous carcinoma present (0/4 submental, 0/2 subdigastric, 0/3 lower jugular, 0/1 mid posterior cervical and 0/4 lower posterior cervical).

MICROSCOPIC FOCUS OF THYROID CARCINOMA IN 1 OF 5 MIDJUGULAR LYMPH NODES.

Right parotid:

Benign salivary gland.

Right modified neck dissection:

Nine lymph nodes, no tumor present (0/1 submental, 0/1 mid-jugular, 0/1 lower jugular, 0/1 upper posterior cervical and 0/2 mid posterior cervical).

(B) LEFT LINGUAL NERVE, BIOPSY:

Benign nerve, no tumor present.

(C) LEFT INFERIOR ALVEOLAR NERVE, PROXIMAL MOST MARGIN:

Benign nerve, no tumor present.

(D) SUBTOTAL MANDIBULECTOMY:

INVASIVE WELL DIFFERENTIATED SQUAMOUS CELL CARCINOMA, MARGINS OF RESECTION FREE OF TUMOR. (SEE COMMENT)

(E) SOFT TISSUE DESIGNATED "NEW MARGIN":

skeletal muscle and adipose tissue, no tumor present.

COMMENT

Representative sections of the mandible to include the medial bone margin of resection are pending decalcification. A supplemental report will be issued upon examination.

SPECIMEN

(A) BILATERAL SUPRAOMOHYOID NECK DISSECTION (20 LYMPH NODES, LEFT AND 9

(B) LEFT LINGUAL NERVE, BIOPSY:

(C) LEFT INFERIOR ALVEOLAR NERVE, PROXIMAL MOST MARGIN:

(D) SUBTOTAL MANDIBULECTOMY:

(E) SOFT TISSUE DESIGNATED "NEW MARGIN":

SNOMED CODES

T-C4200,M-80503,T-11180,M-80703

Source: NCI Genomic Data Commons file 70852cd1-e920-48ee-bc68-a41edeb1e6d8 (TCGA-CV-7411.1D33F5B8-A739-4C18-8A94-78988016A72E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).